Somatic mutation profile of tumor specimen TARGET-10-PARSJG-09A (aliquot TARGET-10-PARSJG-09A-01D) from TARGET case TARGET-10-PARSJG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.0 years (4,371 days).
Specimen TARGET-10-PARSJG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5c183e4-b02d-4b51-a95d-677635814f7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSJG-10A (Blood Derived Normal), aliquot TARGET-10-PARSJG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fa17ba9-4fd3-48a0-9fa6-025ffad18a48

The open-access MAF lists 11 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Intron 3, Nonsense Mutation 1, Frame Shift Del 1, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LEF1 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 62/124 reads (50%) | catalogued as COSV54474534; called by muse, mutect2, varscan2
- NOTCH1 | c.7375del p.Q2459Rfs*18 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as COSV53025731; called by mutect2, pindel, varscan2
- RBFOX1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs757718956, COSV60946461, COSV60979056; called by muse, mutect2, varscan2
- DBH | c.633G>A p.A211= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as rs745489484, COSV55042915; called by muse, mutect2, varscan2
- NTN4 | c.156C>T p.T52= | Silent (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- ULK2 | c.1647C>T p.P549= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs143404110; called by muse, mutect2, varscan2
- USH2A | c.6216G>A p.L2072= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs770033251; called by muse, mutect2, varscan2
- CROCCP2 | n.495+7004G>T | Intron (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- CYBA | c.204-77G>A | Intron (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- MRPS2 | c.300-191G>A | Intron (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- SGCA | c.*22G>T | 3'UTR (SNP) | VAF 19/28 reads (68%) | called by muse, mutect2, varscan2
